Somatic mutation profile of tumor specimen ALCH-ADR9-TTP1-A (aliquot ALCH-ADR9-TTP1-A-1-0-D-A581-36) from ALCHEMIST case ALCH-ADR9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.5 years (19,894 days).
Specimen ALCH-ADR9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c61d61c-4f1d-497d-8fff-4623d956ae00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADR9-NB1-A (Blood Derived Normal), aliquot ALCH-ADR9-NB1-A-1-0-D-A581-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d717cf6f-9558-4ebe-bf7f-5e587f102f05

The open-access MAF lists 1,167 somatic variants for this specimen: 810 protein-altering or splice-affecting, 225 silent, 132 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 672, Silent 225, Nonsense Mutation 69, Intron 53, Splice Site 27, 3'UTR 25, RNA 20, Frame Shift Del 19, 5'UTR 15, 5'Flank 14, Splice Region 11, Frame Shift Ins 7.

Variants (750 of 1,167; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 391/1468 reads (27%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACKR1 | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 38/374 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63671718; called by muse, mutect2
- ADAMTS17 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 130/625 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1032949867; called by muse, mutect2, varscan2
- ADCY2 | c.923C>A p.P308Q | Missense Mutation (SNP) | VAF 48/766 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57868935; called by muse, mutect2
- ADCY8 | c.1993G>C p.E665Q | Missense Mutation (SNP) | VAF 115/1276 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.498); catalogued as COSV53895979; called by muse, mutect2
- ADGRD2 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 51/541 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1317549030; called by muse, mutect2
- ADGRD2 | c.1915G>T p.G639C | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58342498; called by muse, mutect2
- ADGRG4 | c.5828C>A p.S1943* | Nonsense Mutation (SNP) | VAF 70/224 reads (31%) | catalogued as COSV54956852; called by muse, mutect2, varscan2
- ADHFE1 | c.1107C>A p.F369L | Missense Mutation (SNP) | VAF 51/459 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs772098560; called by muse, mutect2, varscan2
- ADRA1A | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1010863998; called by muse, varscan2
- ANAPC1 | c.4769C>T p.P1590L | Missense Mutation (SNP) | VAF 68/1199 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748744660, COSV100595156; called by muse, mutect2
- ANKRD24 | c.1546C>T p.R516* | Nonsense Mutation (SNP) | VAF 72/643 reads (11%) | catalogued as rs979241268, COSV53671997; called by muse, mutect2, varscan2
- ANKRD50 | c.1796G>T p.G599V | Missense Mutation (SNP) | VAF 161/690 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.668); catalogued as COSV72385125; called by muse, mutect2, varscan2
- AOC3 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 65/324 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.093); catalogued as COSV53829456; called by muse, mutect2, varscan2
- AP001781.2 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 80/627 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as rs370171096; called by muse, mutect2, varscan2
- AP002512.3 | c.877G>T p.G293W | Missense Mutation (SNP) | VAF 72/333 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54406531; called by muse, mutect2, varscan2
- APCDD1L | c.476C>A p.A159E | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs1448255918, COSV100954022; called by muse, mutect2, varscan2
- APOE | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 93/718 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1263042140, CM050180; called by muse, mutect2, varscan2
- ARHGAP33 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 48/688 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.387); catalogued as rs748414370; called by muse, mutect2
- ARHGAP35 | c.3160G>A p.G1054R | Missense Mutation (SNP) | VAF 282/940 reads (30%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.516); catalogued as rs781609136; called by muse, mutect2, varscan2
- ART3 | c.1035T>C p.P345= (on ENST00000355810 / NM_001377173.1; = p.P334= on NM_001179.6) | Splice Region (SNP) | VAF 24/130 reads (18%) | catalogued as rs1374136433; called by muse, mutect2, varscan2
- ASTN2 | c.2008T>A p.S670T (on ENST00000313400 / NM_001365069.1; = p.S619T on NM_014010.5) | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV57781313; called by muse, mutect2
- ATP1A4 | c.365C>A p.A122D | Missense Mutation (SNP) | VAF 80/587 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63625503; called by muse, mutect2, varscan2
- AXL | c.1634-1G>T p.X545_splice (on ENST00000301178 / NM_021913.5; = p.X536_splice on NM_001699.6) | Splice Site (SNP) | VAF 42/504 reads (8%) | catalogued as COSV56563684; called by muse, mutect2
- B2M | c.215C>G p.S72* | Nonsense Mutation (SNP) | VAF 108/759 reads (14%) | catalogued as COSV62563374, COSV62563575; called by muse, mutect2, varscan2
- B3GALT1 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 11/251 reads (4%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.936); catalogued as rs1559009718, COSV59909657; called by muse, mutect2
- BAG6 | c.1906C>T p.P636S (on ENST00000676571; = p.P589S on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/598 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.575); catalogued as rs866866020; called by muse, mutect2
- BDP1 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 127/610 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV62431219, COSV62434684; called by muse, mutect2, varscan2
- BHLHE22 | c.1003C>G p.H335D | Missense Mutation (SNP) | VAF 73/722 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.444); catalogued as COSV58861346; called by muse, mutect2, varscan2
- BNC1 | c.1027G>A p.V343M | Missense Mutation (SNP) | VAF 270/1124 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1426036491; called by muse, mutect2, varscan2
- BNC2 | c.2368C>A p.Q790K | Missense Mutation (SNP) | VAF 48/490 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV66155768; called by muse, mutect2
- BRIP1 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 66/981 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs565458815, COSV51995020; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- BRWD1 | c.1468G>C p.D490H | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60898417; called by muse, mutect2, varscan2
- C10orf71 | c.3185C>T p.P1062L | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60505839; called by muse, mutect2, varscan2
- C5orf51 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 68/792 reads (9%) | catalogued as rs750885302; called by muse, mutect2
- C6orf118 | c.1303-1G>A p.X435_splice | Splice Site (SNP) | VAF 29/135 reads (21%) | catalogued as rs767449491; called by muse, mutect2, varscan2
- CACNA1H | c.3543C>A p.D1181E | Missense Mutation (SNP) | VAF 72/359 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.819); catalogued as rs958144782, COSV61987153; called by muse, mutect2, varscan2
- CASS4 | c.1012C>A p.P338T | Missense Mutation (SNP) | VAF 111/708 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV64385669; called by muse, mutect2, varscan2
- CATSPERD | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 192/901 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as rs201522895, COSV100486921; called by muse, mutect2, varscan2
- CCDC168 | c.19401C>A p.N6467K | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1258223457; called by muse, mutect2, varscan2
- CCDC39 | c.1331C>A p.T444N | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); catalogued as COSV56484724; called by muse, mutect2, varscan2
- CCDC74A | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 47/464 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99723587; called by mutect2, varscan2
- CCDC74B | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 42/430 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100134206, COSV60103777; called by muse, mutect2
- CD38 | c.150G>T p.W50C | Missense Mutation (SNP) | VAF 172/848 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56892231; called by muse, mutect2, varscan2
- CDC6 | c.1084-1G>C p.X362_splice | Splice Site (SNP) | VAF 189/1054 reads (18%) | catalogued as COSV52931488, COSV99266484; called by muse, mutect2, varscan2
- CDH10 | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 303/1046 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.209); catalogued as rs903128657, COSV100050371, COSV52573159; called by muse, mutect2, varscan2
- CDH23 | c.3591C>A p.Y1197* | Nonsense Mutation (SNP) | VAF 113/403 reads (28%) | catalogued as COSV99819215, COSV99821789; called by muse, mutect2, varscan2
- CDH4 | c.934G>T p.G312W | Missense Mutation (SNP) | VAF 155/787 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64650323; called by muse, mutect2, varscan2
- CDX4 | c.431C>A p.A144D | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV100999162; called by muse, mutect2, varscan2
- CEP250 | c.4670G>T p.C1557F | Missense Mutation (SNP) | VAF 161/828 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as rs1165795118; called by muse, mutect2, varscan2
- CES3 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 20/162 reads (12%) | catalogued as COSV57593142; called by muse, mutect2, varscan2
- CFAP54 | c.4542G>A p.M1514I | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs781681479; called by muse, mutect2, varscan2
- CGN | c.2915C>T p.S972L | Missense Mutation (SNP) | VAF 76/859 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs746372093, COSV99642781; called by muse, mutect2
- CHIT1 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 233/1101 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99705065; called by muse, mutect2, varscan2
- CHST8 | c.394G>C p.A132P | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV99381775; called by muse, mutect2, varscan2
- CLCN6 | c.1021G>T p.G341W | Missense Mutation (SNP) | VAF 165/844 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100412367; called by muse, mutect2, varscan2
- CNTNAP2 | c.1684C>A p.H562N | Missense Mutation (SNP) | VAF 150/606 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV62220787; called by muse, mutect2, varscan2
- COG2 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 35/462 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV64186329; called by muse, mutect2
- COL16A1 | c.2522G>A p.S841N | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV54710827; called by muse, mutect2
- COL2A1 | c.3083C>T p.T1028M | Missense Mutation (SNP) | VAF 292/939 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs770907704; called by muse, mutect2, varscan2
- COL5A1 | c.1388C>A p.P463Q | Missense Mutation (SNP) | VAF 123/1488 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV65666869; called by muse, mutect2
- COL5A1 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 95/956 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as rs779170635, COSV65669205; ClinVar: uncertain significance; called by muse, mutect2
- COQ8A | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 57/329 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as rs774643334; called by muse, mutect2, varscan2
- CRY1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 50/478 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); catalogued as rs1440795741; called by muse, mutect2, varscan2
- CRYBB3 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 123/983 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV99309226; called by muse, mutect2, varscan2
- CTNNA2 | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 44/690 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100562338; called by muse, mutect2
- CUEDC1 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV64226817; called by muse, mutect2, varscan2
- CUX2 | c.3313C>G p.R1105G | Missense Mutation (SNP) | VAF 159/516 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99920054; called by muse, mutect2, varscan2
- CYBB | c.79G>T p.V27F | Missense Mutation (SNP) | VAF 130/527 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.19); catalogued as rs782168000, COSV101059778; called by muse, mutect2, varscan2
- CYP11B2 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 228/1059 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs562670189, COSV59995904; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CYP1B1 | c.1454C>A p.S485Y | Missense Mutation (SNP) | VAF 248/2168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM116628; called by muse, mutect2, varscan2
- CYP2A6 | c.109C>A p.P37T | Missense Mutation (SNP) | VAF 35/523 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766052140; called by muse, mutect2
- CYP4F2 | c.1249+1G>C p.X417_splice | Splice Site (SNP) | VAF 78/281 reads (28%) | catalogued as rs747558460; called by muse, mutect2, varscan2
- DACH2 | c.988C>A p.P330T | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV64168831; called by muse, mutect2, varscan2
- DDR2 | c.367A>T p.S123C | Missense Mutation (SNP) | VAF 283/1044 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1306367979; called by muse, mutect2, varscan2
- DNAH5 | c.5259G>T p.K1753N | Missense Mutation (SNP) | VAF 116/1465 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.094); catalogued as COSV54225587; called by muse, mutect2
- DNAJC14 | c.2075G>C p.R692P | Missense Mutation (SNP) | VAF 42/416 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); catalogued as COSV99670832; called by muse, mutect2
- DSCAM | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 230/1264 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs369222297, COSV68036796; called by muse, mutect2, varscan2
- DUOX2 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 30/1149 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs1315366889, COSV59909715; called by muse, mutect2
- DZANK1 | c.1542C>G p.I514M (on ENST00000262547 / NM_001099407.1; = p.I321M on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.854); catalogued as rs369323879; called by muse, mutect2
- EDAR | c.1123C>A p.R375S | Missense Mutation (SNP) | VAF 60/617 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51501293; called by muse, mutect2
- EIF2B5 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 231/801 reads (29%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs767998775; called by muse, mutect2, varscan2
- ELAVL2 | c.154C>G p.Q52E | Missense Mutation (SNP) | VAF 36/506 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs1311024648, COSV99807475; called by muse, mutect2
- EMC3 | c.513G>A p.W171* | Nonsense Mutation (SNP) | VAF 89/1071 reads (8%) | catalogued as rs1279503844; called by muse, mutect2
- F8 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100812160; called by muse, mutect2
- FAM71F1 | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 88/233 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100171044; called by muse, mutect2
- FASLG | c.687G>T p.M229I | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV60680809; called by muse, mutect2, varscan2
- FBN2 | c.6394C>A p.P2132T | Missense Mutation (SNP) | VAF 74/558 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52512826; called by muse, mutect2, varscan2
- FBXO42 | c.459A>T p.R153S | Missense Mutation (SNP) | VAF 88/461 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.503); catalogued as rs1278205271; called by muse, mutect2, varscan2
- FCRL5 | c.1029C>A p.F343L | Missense Mutation (SNP) | VAF 71/789 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.022); catalogued as COSV100709149; called by muse, mutect2
- FEZF1 | c.630G>C p.E210D | Missense Mutation (SNP) | VAF 98/1001 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV104402379, COSV58659551; called by muse, mutect2
- FGFRL1 | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 196/791 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.372); catalogued as rs1179855565; called by muse, varscan2
- FIGN | c.735C>A p.Y245* | Nonsense Mutation (SNP) | VAF 58/461 reads (13%) | catalogued as COSV60762365; called by muse, mutect2, varscan2
- FMN2 | c.1432G>C p.G478R | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.99); catalogued as COSV60426112; called by muse, mutect2
- FMN2 | c.4154-1G>A p.X1385_splice | Splice Site (SNP) | VAF 82/458 reads (18%) | catalogued as rs755036020; called by mutect2, varscan2
- FREM3 | c.476C>A p.A159E | Missense Mutation (SNP) | VAF 183/709 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1236400431, COSV61680468; called by muse, mutect2, varscan2
- FRMPD4 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101043787; called by muse, mutect2, varscan2
- FRYL | c.5287G>A p.G1763R | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.888); catalogued as rs769390304; called by muse, mutect2, varscan2
- FRZB | c.529C>G p.R177G | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.483); catalogued as COSV54555460; called by muse, mutect2
- FSTL4 | c.2435C>T p.S812L | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758455610; called by muse, mutect2, varscan2
- GABRG3 | c.543C>G p.D181E | Missense Mutation (SNP) | VAF 109/469 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61531497; called by muse, mutect2, varscan2
- GATA3 | c.1223C>A p.P408H | Missense Mutation (SNP) | VAF 120/986 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV60516666; called by muse, mutect2, varscan2
- GNG4 | c.196C>A p.R66S | Missense Mutation (SNP) | VAF 163/923 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV63999285; called by muse, mutect2, varscan2
- GPR101 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 115/293 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.259); catalogued as COSV99981701; called by muse, mutect2, varscan2
- GREB1 | c.2697G>T p.R899S | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99302033; called by muse, mutect2, varscan2
- GREB1L | c.793G>T p.G265W | Missense Mutation (SNP) | VAF 78/410 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480296285; called by muse, mutect2, varscan2
- GRIN3A | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 64/332 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV62452298, COSV62458577; called by muse, mutect2, varscan2
- HCK | c.1093-1G>C p.X365_splice | Splice Site (SNP) | VAF 11/220 reads (5%) | catalogued as COSV52940407, COSV99393888; called by muse, mutect2
- HCN1 | c.2366C>T p.S789L | Missense Mutation (SNP) | VAF 155/881 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.466); catalogued as COSV100298492, COSV100299654, COSV57536392; called by muse, mutect2, varscan2
- HEPH | c.2564-1G>T p.X855_splice (on ENST00000343002; = p.X588_splice on NM_014799.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100294898; called by muse, mutect2, varscan2
- HEXIM2 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56235956, COSV56236200; called by muse, mutect2, varscan2
- HGF | c.1402C>A p.R468S | Missense Mutation (SNP) | VAF 71/707 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.37); catalogued as COSV55945497; called by muse, mutect2
- HSD3B2 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 274/1366 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV65593857; called by muse, mutect2, varscan2
- HSPG2 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 309/1347 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779022485, COSV101021383; called by muse, mutect2, varscan2
- HTR1A | c.649C>G p.R217G | Missense Mutation (SNP) | VAF 245/1925 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100109187; called by muse, mutect2, varscan2
- HTR1B | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 285/770 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.182); catalogued as rs774927649, COSV64051983; called by muse, mutect2, varscan2
- IGKV1-16 | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 168/978 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs560035671; called by muse, varscan2
- IRF4 | c.1011C>A p.D337E | Missense Mutation (SNP) | VAF 58/518 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0.01); catalogued as COSV66704578, COSV66705441; called by muse, mutect2, varscan2
- JAKMIP1 | c.829G>T p.V277F | Missense Mutation (SNP) | VAF 87/352 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51545488; called by muse, mutect2, varscan2
- JAKMIP2 | c.648G>T p.K216N | Missense Mutation (SNP) | VAF 46/424 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV54608768; called by muse, mutect2
- KCNA2 | c.1276C>A p.Q426K | Missense Mutation (SNP) | VAF 61/659 reads (9%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.665); catalogued as COSV60371278; called by muse, mutect2
- KCNMB4 | c.393G>T p.M131I | Missense Mutation (SNP) | VAF 54/639 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV104382759, COSV50693815; called by muse, mutect2
- KMT2D | c.9470G>A p.G3157E | Missense Mutation (SNP) | VAF 198/647 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.321); catalogued as COSV56429821, COSV56484284; called by muse, mutect2, varscan2
- LARP1 | c.484C>A p.R162S (on ENST00000518297 / NM_033551.3; = p.R85S on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs775862354, COSV60427480; called by muse, mutect2, varscan2
- LCE3B | c.190C>A p.H64N | Missense Mutation (SNP) | VAF 271/751 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100167542, COSV59500621; called by muse, mutect2, varscan2
- LILRB1 | c.289T>C p.Y97H (on ENST00000427581; = p.Y61H on NM_006669.6) | Missense Mutation (SNP) | VAF 180/1118 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as rs1298120204, COSV100207252; called by muse, mutect2
- LILRB3 | c.1269C>G p.D423E | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs766142876; called by muse, mutect2
- LILRB3 | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 122/1731 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.239); catalogued as rs1253380069; called by muse, mutect2
- LINGO1 | c.379C>A p.R127S | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as COSV62436811; called by muse, mutect2, varscan2
- LMOD1 | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 307/1682 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs992229692, COSV66172365; called by muse, mutect2, varscan2
- LMX1A | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 166/759 reads (22%) | catalogued as rs1396081975, COSV54221798; called by muse, mutect2, varscan2
- LRCH1 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 72/692 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1262275437; called by muse, mutect2, varscan2
- LRRTM4 | c.213del p.N71Kfs*41 | Frame Shift Del (DEL) | VAF 102/721 reads (14%) | catalogued as COSV69140795; called by mutect2, pindel, varscan2
- LYPD1 | c.268C>A p.P90T | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.181); catalogued as COSV61417841; called by muse, mutect2, varscan2
- MAP3K8 | c.597G>T p.W199C | Missense Mutation (SNP) | VAF 40/582 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV99552079; called by muse, mutect2
- MAS1 | c.953C>A p.T318K | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.045); catalogued as COSV53121769; called by muse, varscan2
- MFSD5 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 60/436 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100288893; called by muse, mutect2, varscan2
- MICAL2 | c.5329G>C p.E1777Q | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.627); catalogued as rs1181334595, COSV56284800; called by muse, mutect2, varscan2
- MOK | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs757188060; called by muse, mutect2
- MROH2B | c.3338C>A p.S1113Y | Missense Mutation (SNP) | VAF 100/557 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as COSV68183053; called by muse, mutect2, varscan2
- MRPL52 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 49/455 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.623); catalogued as rs147747092; called by muse, mutect2, varscan2
- MUC5B | c.11036C>G p.S3679C | Missense Mutation (SNP) | VAF 61/623 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV71591036; called by muse, mutect2, varscan2
- MXRA8 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV58511074; called by muse, mutect2
- MYH11 | c.7C>A p.Q3K | Missense Mutation (SNP) | VAF 90/738 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs1363516524; called by muse, mutect2, varscan2
- MYORG | c.1481C>A p.A494E | Missense Mutation (SNP) | VAF 42/345 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52626897; called by muse, mutect2, varscan2
- MYRF | c.2081C>A p.T694K (on ENST00000278836 / NM_001127392.3; = p.T685K on NM_013279.4) | Missense Mutation (SNP) | VAF 69/597 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as rs760054506, COSV53886651; called by muse, mutect2, varscan2
- MYT1L | c.2125G>T p.A709S | Missense Mutation (SNP) | VAF 295/969 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as COSV101220730; called by muse, mutect2, varscan2
- NAAA | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 67/601 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs758120876; called by muse, mutect2, varscan2
- NADK | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58271822; called by muse, mutect2, varscan2
- NAGK | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 126/594 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs559948418, COSV99730616; called by muse, mutect2, varscan2
- NBEAL2 | c.6433G>C p.E2145Q | Missense Mutation (SNP) | VAF 68/660 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV52759982; called by muse, mutect2, varscan2
- NCAM1 | c.1114C>A p.R372S (on ENST00000316851 / NM_181351.5; = p.R362S on NM_000615.7) | Missense Mutation (SNP) | VAF 68/353 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs1555117239, COSV100378388; called by muse, mutect2, varscan2
- NCAM1 | c.2041G>A p.E681K (on ENST00000316851 / NM_181351.5; = p.E671K on NM_000615.7) | Missense Mutation (SNP) | VAF 139/908 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100377999, COSV57523945; called by muse, mutect2, varscan2
- NCKIPSD | c.1174C>G p.R392G | Missense Mutation (SNP) | VAF 37/370 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.272); catalogued as COSV99583685; called by muse, mutect2, varscan2
- NLRP3 | c.612G>T p.E204D | Missense Mutation (SNP) | VAF 235/1513 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1015704407; called by muse, mutect2, varscan2
- NMUR2 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 171/627 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54923361; called by muse, mutect2, varscan2
- NOMO2 | c.2145G>T p.E715D | Missense Mutation (SNP) | VAF 216/1646 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100395594; called by muse, mutect2, varscan2
- NPR3 | c.1334G>C p.R445P | Missense Mutation (SNP) | VAF 101/552 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV54093612; called by muse, mutect2, varscan2
- NSMF | c.1050C>T p.L350= (on ENST00000371475 / NM_001130969.3; = p.L348= on NM_015537.4) | Splice Region (SNP) | VAF 36/512 reads (7%) | catalogued as rs1231251007; called by muse, mutect2
- NYAP2 | c.1486G>T p.G496W | Missense Mutation (SNP) | VAF 187/916 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs907521109, COSV56011683; called by muse, mutect2, varscan2
- OR14K1 | c.56G>C p.W19S | Missense Mutation (SNP) | VAF 72/373 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV51720815; called by muse, mutect2, varscan2
- OR1C1 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 109/778 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101376278; called by muse, mutect2, varscan2
- OR2M2 | c.964del p.L322Cfs*8 | Frame Shift Del (DEL) | VAF 49/313 reads (16%) | catalogued as COSV62899405; called by mutect2, varscan2
- OR4C6 | c.445G>C p.G149R | Missense Mutation (SNP) | VAF 102/680 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58605547; called by muse, mutect2, varscan2
- OR5A1 | c.517G>T p.G173* | Nonsense Mutation (SNP) | VAF 77/422 reads (18%) | catalogued as COSV100118475; called by muse, mutect2, varscan2
- P2RY10 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 61/582 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.581); catalogued as rs769579050, COSV50680628; called by muse, mutect2, varscan2
- PAK6 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53048526; called by muse, mutect2, varscan2
- PASK | c.2092G>T p.D698Y | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.7); catalogued as COSV52160395; called by muse, mutect2, varscan2
- PAX5 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 56/463 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV63906191; called by muse, mutect2, varscan2
- PCDH15 | c.2284C>A p.L762I | Missense Mutation (SNP) | VAF 117/708 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.549); catalogued as COSV100216998; called by muse, mutect2, varscan2
- PCDH17 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 125/524 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs760953125, COSV64976241, COSV64979321; called by muse, mutect2, varscan2
- PCDHB7 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 261/1100 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1563919346, COSV50758999, COSV99175216; called by muse, mutect2, varscan2
- PCDHGA5 | c.1718C>A p.T573K | Missense Mutation (SNP) | VAF 230/906 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.701); catalogued as rs777611384, COSV53898348, COSV53907797, COSV53983144; called by muse, mutect2, varscan2
- PCNT | c.2749G>A p.A917T | Missense Mutation (SNP) | VAF 62/612 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs775656915; called by muse, mutect2, varscan2
- PCNX3 | c.3442C>T p.L1148F | Missense Mutation (SNP) | VAF 82/352 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs1411635530; called by muse, mutect2, varscan2
- PEG3 | c.2809G>T p.A937S | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV55635894; called by muse, mutect2, varscan2
- POF1B | c.948C>A p.Y316* | Nonsense Mutation (SNP) | VAF 14/114 reads (12%) | catalogued as COSV99426434; called by muse, varscan2
- POLE4 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.078); catalogued as COSV99284439; called by muse, mutect2, varscan2
- POU4F1 | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.75); catalogued as rs1229533414; called by muse, varscan2
- PPP1R21 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 51/573 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs371203381; called by muse, mutect2
- PRAMEF2 | c.779C>G p.T260S | Missense Mutation (SNP) | VAF 86/1004 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs3204813; called by muse, mutect2
- PRPF40B | c.163-1G>T p.X55_splice (on ENST00000380281; = p.X49_splice on NM_012272.3) | Splice Site (SNP) | VAF 117/1184 reads (10%) | catalogued as COSV56057486; called by muse, mutect2
- PRR23A | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV101270325; called by muse, mutect2, varscan2
- PRR30 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 59/1075 reads (5%) | catalogued as rs1011662920, COSV99574294; called by muse, mutect2
- PTPN13 | c.2764G>T p.V922F | Missense Mutation (SNP) | VAF 38/489 reads (8%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.926); catalogued as COSV57411361; called by muse, mutect2
- PTPRR | c.352G>T p.V118L | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV51749420; called by muse, mutect2
- RAX | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1178558773; called by muse, mutect2, varscan2
- RBFOX1 | c.303C>G p.N101K | Missense Mutation (SNP) | VAF 35/358 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs1457072919; called by muse, mutect2
- RBM48 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 48/459 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV99720138; called by muse, mutect2, varscan2
- RHAG | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 187/930 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100006810; called by muse, mutect2, varscan2
- RIMBP2 | c.1409G>T p.R470M | Missense Mutation (SNP) | VAF 60/450 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99898722; called by muse, mutect2
- RIMS2 | c.3239C>G p.S1080W (on ENST00000666250 / NM_001348490.2; = p.S888W on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV51656632, COSV51697680; called by muse, varscan2
- RYR2 | c.9768C>A p.N3256K | Missense Mutation (SNP) | VAF 89/631 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV63672587; called by muse, mutect2, varscan2
- SDK1 | c.6263G>A p.R2088Q | Missense Mutation (SNP) | VAF 44/337 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs546205984; called by muse, mutect2, varscan2
- SLC12A9 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs756372119; called by muse, mutect2, varscan2
- SLC4A11 | c.2404G>A p.V802I | Missense Mutation (SNP) | VAF 75/521 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs1305167528; called by muse, mutect2, varscan2
- SLC5A1 | c.1666-2A>T p.X556_splice | Splice Site (SNP) | VAF 156/956 reads (16%) | catalogued as CD042616; called by muse, mutect2, varscan2
- SPTA1 | c.6198G>T p.L2066F | Missense Mutation (SNP) | VAF 31/461 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773750489; called by muse, mutect2
- SPTBN4 | c.5500C>T p.R1834W | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.965); catalogued as rs554419213; called by muse, mutect2, varscan2
- SRGAP1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 329/644 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs757594295; called by muse, mutect2, varscan2
- SSC5D | c.1325C>G p.T442R | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV67477195; called by muse, mutect2
- STAG2 | c.1298A>G p.Y433C | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.765); catalogued as rs764885530; called by muse, mutect2, varscan2
- STXBP5L | c.1247C>A p.A416E | Missense Mutation (SNP) | VAF 50/511 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV56541466; called by muse, mutect2, varscan2
- SUPT6H | c.1727G>C p.S576T | Missense Mutation (SNP) | VAF 65/516 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.024); catalogued as COSV100112143; called by muse, mutect2, varscan2
- TGFBR1 | c.413G>T p.C138F | Missense Mutation (SNP) | VAF 214/906 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV66626881; called by muse, mutect2, varscan2
- TGM1 | c.362G>C p.R121P | Missense Mutation (SNP) | VAF 123/383 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV52861541; called by muse, mutect2, varscan2
- TIAM2 | c.3223G>T p.G1075C | Missense Mutation (SNP) | VAF 38/350 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV51640713; called by muse, mutect2, varscan2
- TLN1 | c.6530G>T p.R2177L | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV59212812; called by muse, mutect2
- TMEM196 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 46/556 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs1328050808, COSV68254865; called by muse, mutect2
- TMEM225 | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 42/412 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV66693427; called by muse, mutect2
- TMPRSS15 | c.772C>A p.R258S | Missense Mutation (SNP) | VAF 246/846 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.114); catalogued as COSV53039591, COSV53044297; called by muse, mutect2, varscan2
- TNRC6A | c.5626G>T p.G1876W | Missense Mutation (SNP) | VAF 162/640 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747960863; called by muse, mutect2, varscan2
- TPX2 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 72/381 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV55920950; called by muse, mutect2, varscan2
- TRBV7-1 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 192/673 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1463800528; called by muse, mutect2, varscan2
- TRIM28 | c.252G>T p.L84F | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV53401374; called by muse, mutect2, varscan2
- TRPC4 | c.574C>G p.H192D | Missense Mutation (SNP) | VAF 141/579 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100157263; called by muse, mutect2, varscan2
- TRPM5 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs539036580; called by muse, mutect2, varscan2
- TUFM | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 36/1401 reads (3%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV100493239, COSV100493242; called by muse, mutect2
- UGT2B10 | c.956G>T p.R319M | Missense Mutation (SNP) | VAF 140/682 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as COSV55320944; called by muse, mutect2, varscan2
- UNC80 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 47/452 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.362); catalogued as rs765134450; called by muse, mutect2, varscan2
- UNC80 | c.6926G>A p.G2309E | Missense Mutation (SNP) | VAF 117/576 reads (20%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); catalogued as rs1376525983, COSV55891682; called by muse, mutect2, varscan2
- USH2A | c.4466C>T p.P1489L | Missense Mutation (SNP) | VAF 102/550 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs1397675655; called by muse, mutect2, varscan2
- USH2A | c.654G>T p.V218= | Splice Region (SNP) | VAF 60/298 reads (20%) | catalogued as COSV56424515; called by muse, mutect2, varscan2
- USP15 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54790141, COSV99740174; called by muse, mutect2
- USP51 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as COSV72351819; called by muse, mutect2, varscan2
- VN1R2 | c.154G>C p.V52L | Missense Mutation (SNP) | VAF 127/470 reads (27%) | PolyPhen benign (0.097); catalogued as COSV59038497; called by muse, mutect2, varscan2
- VRTN | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as rs201579420; called by muse, mutect2
- WASHC4 | c.2495C>T p.T832M | Missense Mutation (SNP) | VAF 96/1540 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.917); catalogued as rs765821676, COSV100161991; called by muse, mutect2
- WDR81 | c.1045G>T p.V349L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs150798889; called by muse, mutect2, varscan2
- WNK1 | c.3469G>T p.E1157* (on ENST00000315939 / NM_018979.4; = p.E910* on NM_014823.3) | Nonsense Mutation (SNP) | VAF 123/1186 reads (10%) | catalogued as COSV100266592; called by muse, mutect2
- XIRP2 | c.1283T>A p.I428N (on ENST00000628543; = p.I603N on NM_152381.6) | Missense Mutation (SNP) | VAF 105/633 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs1302444701; called by muse, mutect2, varscan2
- XIRP2 | c.1634C>A p.S545Y (on ENST00000628543; = p.S720Y on NM_152381.6) | Missense Mutation (SNP) | VAF 49/361 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99746780; called by muse, mutect2, varscan2
- XIRP2 | c.6722C>A p.T2241N (on ENST00000628543; = p.T2416N on NM_152381.6) | Missense Mutation (SNP) | VAF 39/329 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV54689479; called by muse, mutect2, varscan2
- ZBTB33 | c.392A>T p.Q131L | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs782716913; called by muse, mutect2, varscan2
- ZDHHC9 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 53/421 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1177381912; called by muse, mutect2, varscan2
- ZFHX4 | c.6539C>A p.T2180K | Missense Mutation (SNP) | VAF 57/585 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV51454526, COSV99268633; called by muse, mutect2, varscan2
- ZNF175 | c.380G>C p.R127T | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV51794974; called by muse, mutect2
- ZNF432 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 14/335 reads (4%) | catalogued as COSV55415649, COSV99659388; called by muse, mutect2
- ZNF467 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1381715441, COSV100118180; called by muse, mutect2, varscan2
- ZNF471 | c.1624C>A p.P542T | Missense Mutation (SNP) | VAF 71/515 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376984216; called by muse, mutect2, varscan2
- ZNF536 | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100834652, COSV62827356; called by muse, mutect2, varscan2
- ZNF646 | c.4636C>T p.L1546F | Missense Mutation (SNP) | VAF 129/588 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs1471343766; called by muse, mutect2, varscan2
- ZNF701 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 84/941 reads (9%) | catalogued as COSV56526795; called by muse, mutect2
- ZNF91 | c.1607A>C p.H536P | Missense Mutation (SNP) | VAF 84/359 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100322513; called by muse, mutect2, varscan2
- ABCA13 | c.14818C>A p.P4940T | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2
- ABCA2 | c.2985G>T p.Q995H (on ENST00000614293; = p.Q965H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/339 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2
- ABHD5 | c.526G>C p.V176L | Missense Mutation (SNP) | VAF 90/793 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- AC026316.4 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 57/542 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ACOT11 | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 82/397 reads (21%) | called by muse, mutect2, varscan2
- ACVRL1 | c.217C>A p.H73N | Missense Mutation (SNP) | VAF 121/965 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM22 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 131/617 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS10 | c.1262C>A p.A421D | Missense Mutation (SNP) | VAF 156/626 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADAMTS17 | c.2138-2A>G p.X713_splice | Splice Site (SNP) | VAF 332/1557 reads (21%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.60G>T p.R20S | Missense Mutation (SNP) | VAF 106/644 reads (16%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTS7 | c.2811C>A p.N937K | Missense Mutation (SNP) | VAF 140/599 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ADCY2 | c.922C>A p.P308T | Missense Mutation (SNP) | VAF 50/762 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGB | c.2812A>T p.S938C | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- ADGRL2 | c.914T>C p.V305A | Missense Mutation (SNP) | VAF 184/1168 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL2 | c.2360A>T p.N787I (on ENST00000370717 / NM_001366005.1; = p.N774I on NM_012302.4) | Missense Mutation (SNP) | VAF 94/740 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADGRL3 | c.1990G>T p.D664Y (on ENST00000506720 / NM_001322402.2; = p.D596Y on NM_015236.6) | Missense Mutation (SNP) | VAF 46/581 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2
- ADNP | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 170/758 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- AFF2 | c.1598G>C p.W533S | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGBL5 | c.1058G>C p.S353T | Missense Mutation (SNP) | VAF 100/1226 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- AGTRAP | c.299C>G p.P100R | Missense Mutation (SNP) | VAF 100/558 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK | c.5858G>T p.G1953V | Missense Mutation (SNP) | VAF 190/1556 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP13 | c.3064G>T p.A1022S | Missense Mutation (SNP) | VAF 28/307 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.193); called by muse, mutect2
- ALPK2 | c.2791C>A p.Q931K | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALPP | c.439C>A p.R147S | Missense Mutation (SNP) | VAF 83/722 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.035); called by muse, mutect2
- AMIGO2 | c.1406T>C p.L469S | Missense Mutation (SNP) | VAF 170/856 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ANKRD13B | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 97/392 reads (25%) | called by muse, mutect2, varscan2
- ANKRD30B | c.3605C>T p.A1202V | Missense Mutation (SNP) | VAF 27/341 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2
- ANKRD42 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 117/871 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD66 | c.694A>G p.K232E | Missense Mutation (SNP) | VAF 93/550 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ANLN | c.1651G>C p.E551Q | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- APOBR | c.2557A>G p.T853A (on ENST00000431282; = p.T862A on NM_018690.4) | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AQP5 | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- ARCN1 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 126/1229 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ARHGAP20 | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 83/498 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- ARHGEF17 | c.3641C>T p.P1214L | Missense Mutation (SNP) | VAF 73/734 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF25 | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 42/744 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- ARHGEF3 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 101/400 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- ART5 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 41/400 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ARX | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ASTN1 | c.434C>A p.A145E | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.173); called by muse, varscan2
- ATP11A | c.733G>T p.G245* | Nonsense Mutation (SNP) | VAF 140/638 reads (22%) | called by muse, mutect2, varscan2
- ATP1A4 | c.1491G>T p.Q497H | Missense Mutation (SNP) | VAF 48/510 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- ATP1A4 | c.2222G>A p.G741D | Missense Mutation (SNP) | VAF 46/786 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP4A | c.848C>G p.S283W | Missense Mutation (SNP) | VAF 76/785 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- ATRN | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ATXN1L | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.159); called by muse, varscan2
- AUNIP | c.221-1G>A p.X74_splice | Splice Site (SNP) | VAF 21/107 reads (20%) | called by muse, varscan2
- AXL | c.1634G>T p.G545V (on ENST00000301178 / NM_021913.5; = p.G536V on NM_001699.6) | Missense Mutation (SNP) | VAF 43/508 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- B3GNT5 | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 56/578 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- BAAT | c.830C>A p.P277H | Missense Mutation (SNP) | VAF 129/588 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BCAR1 | c.2035C>T p.Q679* | Nonsense Mutation (SNP) | VAF 54/622 reads (9%) | called by muse, mutect2
- BCAR1 | c.656G>C p.G219A | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- BEX3 | c.139T>A p.F47I | Missense Mutation (SNP) | VAF 104/614 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- BICC1 | c.1820G>T p.G607V | Missense Mutation (SNP) | VAF 79/482 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- BNIP1 | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 58/447 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BOLL | c.472C>G p.P158A | Missense Mutation (SNP) | VAF 36/439 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- BRIP1 | c.2707C>A p.Q903K | Missense Mutation (SNP) | VAF 113/608 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BTAF1 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 171/613 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- BTBD17 | c.830_831del p.R277Pfs*180 | Frame Shift Del (DEL) | VAF 37/299 reads (12%) | called by pindel, varscan2
- BZW2 | c.405G>A p.K135= | Splice Region (SNP) | VAF 18/266 reads (7%) | called by muse, mutect2
- C11orf65 | c.535A>T p.R179* | Nonsense Mutation (SNP) | VAF 78/395 reads (20%) | called by muse, mutect2, varscan2
- C12orf40 | c.1323G>C p.Q441H | Missense Mutation (SNP) | VAF 67/327 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- C1orf167 | c.143del p.G48Efs*17 | Frame Shift Del (DEL) | VAF 18/130 reads (14%) | called by mutect2, pindel
- C1orf94 | c.341G>C p.G114A | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.199); called by muse, mutect2
- C2CD4D | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- C2orf81 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- C4orf54 | c.4944G>T p.M1648I | Missense Mutation (SNP) | VAF 84/676 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- CA3 | c.230C>G p.S77* | Nonsense Mutation (SNP) | VAF 45/359 reads (13%) | called by muse, mutect2, varscan2
- CAAP1 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- CACNA1A | c.1658G>T p.C553F | Missense Mutation (SNP) | VAF 106/622 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CACNA1E | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 88/343 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CALB2 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 56/515 reads (11%) | called by muse, mutect2, varscan2
- CAMP | c.474G>C p.Q158H (on ENST00000296435; = p.Q155H on NM_004345.5) | Missense Mutation (SNP) | VAF 28/1056 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.66); called by muse, mutect2
- CASP7 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 103/687 reads (15%) | called by muse, mutect2, varscan2
- CCDC12 | c.280A>G p.K94E (on ENST00000425441 / NM_001277074.1; = p.K107E on NM_144716.5) | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, varscan2
- CCDC168 | c.11267del p.P3756Hfs*2 | Frame Shift Del (DEL) | VAF 71/372 reads (19%) | called by mutect2, pindel, varscan2
- CCL18 | c.269G>T p.*90Lext*35 | Nonstop Mutation (SNP) | VAF 96/394 reads (24%) | called by muse, mutect2, varscan2
- CD244 | c.400G>C p.V134L (on ENST00000368033 / NM_001166663.2; = p.V129L on NM_016382.4) | Missense Mutation (SNP) | VAF 91/380 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- CD27 | c.146T>A p.L49H | Missense Mutation (SNP) | VAF 83/330 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CD52 | c.71C>G p.S24* | Nonsense Mutation (SNP) | VAF 30/898 reads (3%) | called by muse, mutect2
- CDC14B | c.533C>A p.T178K | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- CDH10 | c.1768G>C p.D590H | Missense Mutation (SNP) | VAF 207/1552 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDH22 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 98/667 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH23 | c.6148A>T p.N2050Y | Missense Mutation (SNP) | VAF 132/1220 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CDH9 | c.1862T>A p.L621H | Missense Mutation (SNP) | VAF 93/567 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CELSR3 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- CEP290 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 611/1247 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CEP350 | c.1619C>T p.T540I | Missense Mutation (SNP) | VAF 124/704 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CEP43 | c.698G>A p.R233K | Missense Mutation (SNP) | VAF 116/876 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEPT1 | c.712A>T p.M238L | Missense Mutation (SNP) | VAF 59/384 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP47 | c.738G>T p.M246I | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP47 | c.4889A>G p.Q1630R | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CFHR4 | c.1103C>A p.A368E (on ENST00000367416 / NM_001201551.2; = p.A122E on NM_006684.5) | Missense Mutation (SNP) | VAF 103/585 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- CHD6 | c.5430A>T p.L1810F | Missense Mutation (SNP) | VAF 47/321 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHI3L1 | c.982T>A p.Y328N | Missense Mutation (SNP) | VAF 83/1148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHN1 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 67/544 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CHRNB4 | c.522G>A p.W174* | Nonsense Mutation (SNP) | VAF 119/355 reads (34%) | called by muse, mutect2, varscan2
- CIAO3 | c.1038C>A p.N346K | Missense Mutation (SNP) | VAF 60/259 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CIB4 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 42/488 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- CLASP1 | c.2678A>T p.E893V | Missense Mutation (SNP) | VAF 94/464 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- CLCA2 | c.2091A>G p.I697M | Missense Mutation (SNP) | VAF 69/370 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMYA5 | c.2167_2168dup p.L723Ffs*2 | Frame Shift Ins (INS) | VAF 57/321 reads (18%) | called by mutect2, pindel, varscan2
- COL1A2 | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 106/1202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL6A3 | c.7283T>C p.I2428T | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- COL6A5 | c.2180G>C p.G727A | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- COL9A3 | c.1132C>A p.R378S | Missense Mutation (SNP) | VAF 132/632 reads (21%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL9A3 | c.1652G>T p.G551V | Missense Mutation (SNP) | VAF 245/1232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CREB5 | c.488C>G p.S163C (on ENST00000357727 / NM_182898.4; = p.S156C on NM_004904.3) | Missense Mutation (SNP) | VAF 162/614 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CRTAM | c.112T>A p.C38S | Missense Mutation (SNP) | VAF 40/459 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRYBG3 | c.1483G>T p.A495S | Missense Mutation (SNP) | VAF 106/502 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- CSMD3 | c.11025_11026insC p.A3676Rfs*3 (on ENST00000297405 / NM_001363185.1; = p.A3507Rfs*3 on NM_052900.3) | Frame Shift Ins (INS) | VAF 107/1062 reads (10%) | called by mutect2, pindel, varscan2
- CSMD3 | c.7595A>T p.Y2532F (on ENST00000297405 / NM_001363185.1; = p.Y2428F on NM_052900.3) | Missense Mutation (SNP) | VAF 68/767 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.403); called by muse, mutect2
- CSMD3 | c.992G>T p.S331I | Missense Mutation (SNP) | VAF 161/731 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- CSNK1D | c.454C>A p.L152M | Missense Mutation (SNP) | VAF 268/1498 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- CUBN | c.6503C>A p.P2168H | Missense Mutation (SNP) | VAF 109/578 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CUL9 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CYLC2 | c.58G>T p.V20F | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CYP3A43 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.266); called by muse, mutect2
- DBH | c.20G>T p.W7L | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.018); called by muse, mutect2
- DCAF1 | c.2234del p.K745Rfs*18 | Frame Shift Del (DEL) | VAF 156/876 reads (18%) | called by mutect2, pindel, varscan2
- DCHS1 | c.4128G>T p.E1376D | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCLK3 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 115/696 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DDR2 | c.2210G>A p.S737N | Missense Mutation (SNP) | VAF 155/772 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- DDX43 | c.1608C>G p.G536= | Splice Region (SNP) | VAF 54/311 reads (17%) | called by muse, mutect2, varscan2
- DDX53 | c.1771C>G p.Q591E | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- DENND5B | c.3466+1G>T p.X1156_splice | Splice Site (SNP) | VAF 126/467 reads (27%) | called by muse, mutect2, varscan2
- DEPDC1 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DGKK | c.572G>C p.R191T | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2
- DHX36 | c.969-1G>T p.X323_splice | Splice Site (SNP) | VAF 25/198 reads (13%) | called by muse, mutect2, varscan2
- DISP3 | c.715C>A p.H239N | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2
- DLG5 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 377/1414 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DMD | c.3308C>G p.P1103R | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DMTF1 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 21/662 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); called by muse, mutect2
- DNAH10 | c.592C>A p.L198I (on ENST00000409039; = p.L137I on NM_207437.3) | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DNAH10 | c.641C>G p.S214C (on ENST00000409039; = p.S153C on NM_207437.3) | Missense Mutation (SNP) | VAF 63/432 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- DNAH11 | c.12062G>T p.S4021I | Missense Mutation (SNP) | VAF 78/685 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- DNAH5 | c.7894A>T p.I2632L | Missense Mutation (SNP) | VAF 141/1046 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- DNAJC1 | c.139G>C p.G47R | Missense Mutation (SNP) | VAF 52/356 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, varscan2
- DOCK9 | c.4088A>T p.Q1363L (on ENST00000376460 / NM_001366676.2; = p.Q1364L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/561 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2
- DPF3 | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 103/635 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- DPH2 | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 108/1175 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2
- DPM3 | c.103C>T p.Q35* (on ENST00000341298; = p.Q65* on NM_018973.3) | Nonsense Mutation (SNP) | VAF 38/538 reads (7%) | called by muse, mutect2
- DSG2 | c.626del p.P209Qfs*5 | Frame Shift Del (DEL) | VAF 105/685 reads (15%) | called by mutect2, pindel*, varscan2
- DSPP | c.526G>T p.V176F | Missense Mutation (SNP) | VAF 80/600 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- ECPAS | c.4336+1G>T p.X1446_splice | Splice Site (SNP) | VAF 42/608 reads (7%) | called by muse, mutect2
- ECPAS | c.4336G>T p.E1446* | Nonsense Mutation (SNP) | VAF 42/613 reads (7%) | called by muse, mutect2
- EDEM3 | c.2653A>G p.N885D | Missense Mutation (SNP) | VAF 44/578 reads (8%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2
- EDIL3 | c.1434G>T p.E478D | Missense Mutation (SNP) | VAF 87/852 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EFCAB7 | c.382T>G p.Y128D | Missense Mutation (SNP) | VAF 71/360 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- EFCC1 | c.973C>G p.R325G | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EFHB | c.590C>A p.T197N | Missense Mutation (SNP) | VAF 93/407 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- EFR3A | c.2084G>T p.R695I | Missense Mutation (SNP) | VAF 40/421 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2
- ELFN1 | c.1541G>A p.S514N | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- ELOA | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 137/1227 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- EMC1 | c.2517C>G p.I839M | Missense Mutation (SNP) | VAF 65/621 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- EMID1 | c.1075-1G>T p.X359_splice | Splice Site (SNP) | VAF 110/532 reads (21%) | called by muse, varscan2
- EP400 | c.8809G>A p.A2937T | Missense Mutation (SNP) | VAF 141/535 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EPB41L5 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 32/345 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- EPB41L5 | c.1888-2A>G p.X630_splice | Splice Site (SNP) | VAF 105/460 reads (23%) | called by muse, mutect2, varscan2
- EPC2 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 42/512 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPHB1 | c.40G>C p.A14P | Missense Mutation (SNP) | VAF 69/705 reads (10%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ERN2 | c.78del p.T27Rfs*2 | Frame Shift Del (DEL) | VAF 48/225 reads (21%) | called by mutect2, pindel, varscan2
- ERVW-1 | c.1396C>A p.P466T | Missense Mutation (SNP) | VAF 147/663 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2
- ESPL1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ESPNL | c.1269G>C p.Q423H | Missense Mutation (SNP) | VAF 59/366 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESYT2 | c.224G>T p.R75M | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); called by muse, mutect2
- FAM171A1 | c.1957A>C p.T653P | Missense Mutation (SNP) | VAF 69/356 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- FAM209B | c.77G>A p.R26K | Missense Mutation (SNP) | VAF 118/1438 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.022); called by muse, mutect2
- FBXL16 | c.372G>T p.W124C | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- FBXO40 | c.162C>A p.H54Q | Missense Mutation (SNP) | VAF 102/362 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO40 | c.163C>A p.Q55K | Missense Mutation (SNP) | VAF 102/359 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FCGBP | c.1454G>C p.G485A | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FCHO1 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 25/226 reads (11%) | called by muse, mutect2, varscan2
- FER1L6 | c.5332G>T p.A1778S | Missense Mutation (SNP) | VAF 59/553 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- FGF3 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 608/1525 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG | c.11734C>A p.H3912N | Missense Mutation (SNP) | VAF 570/2493 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- FLYWCH1 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 130/661 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- FOXS1 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FSHR | c.1889C>A p.T630N | Missense Mutation (SNP) | VAF 164/2125 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- FTO | c.977G>C p.C326S | Missense Mutation (SNP) | VAF 320/1619 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FTSJ1 | c.295A>G p.K99E | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2
- FZD6 | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 35/376 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GALR2 | c.737G>A p.C246Y | Missense Mutation (SNP) | VAF 68/411 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GAPDHS | c.448T>A p.C150S | Missense Mutation (SNP) | VAF 75/714 reads (11%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- GAS2L1 | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- GBE1 | c.913G>T p.G305W | Missense Mutation (SNP) | VAF 104/463 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- GBX2 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- GCN1 | c.6745G>T p.E2249* | Nonsense Mutation (SNP) | VAF 148/589 reads (25%) | called by muse, mutect2, varscan2
- GDF2 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 44/818 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.644); called by muse, mutect2
- GFPT2 | c.1357A>T p.S453C | Missense Mutation (SNP) | VAF 121/531 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GGA1 | c.298C>G p.P100A | Missense Mutation (SNP) | VAF 46/439 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- GHDC | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- GIMAP2 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 298/912 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLB1L3 | c.1779+5G>T | Splice Region (SNP) | VAF 134/1510 reads (9%) | called by muse, mutect2
- GNB5 | c.117T>A p.C39* | Nonsense Mutation (SNP) | VAF 64/425 reads (15%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.650+2T>C p.X217_splice | Splice Site (SNP) | VAF 112/730 reads (15%) | called by muse, mutect2, varscan2
- GP5 | c.410T>A p.I137N | Missense Mutation (SNP) | VAF 90/1284 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2
- GPC5 | c.1602C>G p.I534M | Missense Mutation (SNP) | VAF 62/246 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- GPR142 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 59/282 reads (21%) | called by muse, mutect2
- GREB1 | c.5582C>G p.S1861C | Missense Mutation (SNP) | VAF 66/842 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRID2 | c.1280G>C p.G427A | Missense Mutation (SNP) | VAF 57/278 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GRIP1 | c.1268G>C p.G423A (on ENST00000359742 / NM_001379345.1; = p.G371A on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 199/1599 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GTPBP1 | c.1985G>T p.C662F | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HGFAC | c.1885G>T p.G629W | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN2 | c.11684G>T p.G3895V | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMGN3 | c.212G>C p.G71A | Missense Mutation (SNP) | VAF 80/425 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- HMGXB4 | c.1799G>T p.G600V | Missense Mutation (SNP) | VAF 49/443 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNF4A | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 84/998 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.103); called by muse, mutect2
- HNRNPL | c.199G>C p.G67R | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HOOK2 | c.1836G>T p.Q612H | Missense Mutation (SNP) | VAF 101/394 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- HOOK2 | c.1730G>T p.R577L | Missense Mutation (SNP) | VAF 72/289 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HOXA5 | c.449A>T p.E150V | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- HOXB4 | c.576G>C p.R192S | Missense Mutation (SNP) | VAF 59/761 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HRNR | c.1430G>T p.G477V | Missense Mutation (SNP) | VAF 367/1724 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- HSPG2 | c.1017_1018insCCTT p.K340Pfs*2 | Frame Shift Ins (INS) | VAF 82/856 reads (10%) | called by mutect2, pindel
- ICAM4 | c.335A>T p.H112L | Missense Mutation (SNP) | VAF 70/246 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IFI44L | c.575C>A p.A192E | Missense Mutation (SNP) | VAF 73/387 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- IFNL3 | c.367dup p.L123Pfs*90 | Frame Shift Ins (INS) | VAF 43/415 reads (10%) | called by mutect2, varscan2
- IGDCC3 | c.2365G>T p.G789C | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- IGLON5 | c.237G>T p.W79C | Missense Mutation (SNP) | VAF 48/437 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGSF10 | c.6564T>A p.D2188E | Missense Mutation (SNP) | VAF 97/477 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- IL36A | c.406T>A p.C136S | Missense Mutation (SNP) | VAF 174/939 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ILF2 | c.578-1G>A p.X193_splice | Splice Site (SNP) | VAF 202/918 reads (22%) | called by muse, mutect2, varscan2
- IMPG2 | c.2328A>G p.I776M | Missense Mutation (SNP) | VAF 228/1029 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INPPL1 | c.3719G>C p.G1240A | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- INSRR | c.2844-1G>C p.X948_splice | Splice Site (SNP) | VAF 43/1593 reads (3%) | called by muse, mutect2
- INTS3 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 76/572 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- IRAK3 | c.1274G>T p.C425F | Missense Mutation (SNP) | VAF 769/1509 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IREB2 | c.1481G>C p.G494A | Missense Mutation (SNP) | VAF 80/352 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA10 | c.2764G>T p.G922W | Missense Mutation (SNP) | VAF 144/876 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- ITGA2B | c.2738C>A p.S913* | Nonsense Mutation (SNP) | VAF 150/749 reads (20%) | called by muse, mutect2, varscan2
- ITGAV | c.1948G>T p.G650W | Missense Mutation (SNP) | VAF 56/379 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ITPR3 | c.1750C>T p.Q584* | Nonsense Mutation (SNP) | VAF 77/473 reads (16%) | called by muse, mutect2, varscan2
- ITPR3 | c.5063A>T p.K1688M | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- JAKMIP2 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 47/433 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- KATNBL1 | c.699-1G>C p.X233_splice | Splice Site (SNP) | VAF 13/288 reads (5%) | called by muse, mutect2
- KCNH2 | c.828C>A p.C276* | Nonsense Mutation (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- KCNH4 | c.666C>A p.Y222* | Nonsense Mutation (SNP) | VAF 56/614 reads (9%) | called by muse, mutect2
- KCNH8 | c.2876G>T p.W959L | Missense Mutation (SNP) | VAF 125/559 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KCNJ11 | c.935del p.G312Afs*8 | Frame Shift Del (DEL) | VAF 80/830 reads (10%) | called by mutect2, pindel, varscan2
- KCNK2 | c.233C>A p.T78N (on ENST00000444842 / NM_001017425.3; = p.T63N on NM_014217.4) | Missense Mutation (SNP) | VAF 156/1077 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- KCNQ5 | c.2365G>T p.E789* | Nonsense Mutation (SNP) | VAF 185/1130 reads (16%) | called by muse, mutect2, varscan2
- KCNU1 | c.581-2A>T p.X194_splice | Splice Site (SNP) | VAF 53/391 reads (14%) | called by muse, mutect2, varscan2
- KHNYN | c.708C>A p.D236E | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIAA0100 | c.1415G>T p.W472L | Missense Mutation (SNP) | VAF 68/535 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA1217 | c.3659G>C p.R1220T | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- KIAA1328 | c.1155G>C p.Q385H | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1755 | c.2169+1G>C p.X723_splice | Splice Site (SNP) | VAF 95/620 reads (15%) | called by muse, mutect2, varscan2
- KIF1C | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 19/492 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.227); called by muse, mutect2
- KIF21B | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 52/377 reads (14%) | called by muse, mutect2, varscan2
- KIF5A | c.2381T>A p.L794H | Missense Mutation (SNP) | VAF 206/3570 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIF5B | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 63/430 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KPNA5 | c.396T>A p.F132L | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.991); called by muse, mutect2
- KRTAP12-4 | c.128C>G p.A43G | Missense Mutation (SNP) | VAF 113/417 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRTAP13-1 | c.68C>G p.A23G | Missense Mutation (SNP) | VAF 140/487 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP4-6 | c.37C>G p.Q13E | Missense Mutation (SNP) | VAF 54/407 reads (13%) | SIFT tolerated (0.16); called by muse, mutect2, varscan2
- KRTAP9-3 | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 177/2539 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.308); called by muse, mutect2
- LAMC1 | c.1321G>T p.G441* | Nonsense Mutation (SNP) | VAF 132/548 reads (24%) | called by muse, mutect2, varscan2
- LAMTOR4 | c.176T>A p.M59K | Missense Mutation (SNP) | VAF 186/788 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- LARGE1 | c.1984G>T p.V662F | Missense Mutation (SNP) | VAF 116/1296 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2
- LDLRAD4 | c.314G>T p.R105M | Missense Mutation (SNP) | VAF 100/543 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- LDLRAD4 | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 170/917 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- LENG8 | c.1756G>T p.V586F | Missense Mutation (SNP) | VAF 56/636 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LILRB5 | c.200G>T p.W67L | Missense Mutation (SNP) | VAF 104/1184 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2
- LIPN | c.111T>A p.S37R | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMCD1 | c.742G>T p.G248* | Nonsense Mutation (SNP) | VAF 124/512 reads (24%) | called by muse, mutect2, varscan2
- LRBA | c.6423C>G p.I2141M | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2
- LRRC3C | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 18/291 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2
- LRRC53 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 271/1261 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- LRRC66 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 213/766 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC66 | c.954G>T p.R318S | Missense Mutation (SNP) | VAF 62/732 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.019); called by muse, mutect2
- LRRC70 | c.1082G>T p.W361L | Missense Mutation (SNP) | VAF 44/1084 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.137); called by muse, mutect2
- LRRK2 | c.6374C>A p.S2125Y | Missense Mutation (SNP) | VAF 64/700 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- LYPLAL1 | c.164A>T p.K55I | Missense Mutation (SNP) | VAF 90/480 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MACC1 | c.2464A>T p.T822S | Missense Mutation (SNP) | VAF 56/463 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MAGEA12 | c.698G>C p.G233A | Missense Mutation (SNP) | VAF 204/568 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MAGEB10 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 70/304 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- MAGI2 | c.3541C>A p.P1181T | Missense Mutation (SNP) | VAF 108/476 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K6 | c.1979G>T p.G660V | Missense Mutation (SNP) | VAF 62/680 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP4 | c.377G>T p.C126F | Missense Mutation (SNP) | VAF 48/556 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2
- MBD3L3 | c.603G>T p.Q201H | Missense Mutation (SNP) | VAF 96/1758 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2
- MCF2L2 | c.3343T>C p.*1115Rext*60 | Nonstop Mutation (SNP) | VAF 38/118 reads (32%) | called by muse, mutect2, varscan2
- MCM4 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 148/597 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- MCOLN3 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 121/646 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MED12 | c.5320del p.A1774Lfs*41 | Frame Shift Del (DEL) | VAF 28/219 reads (13%) | called by mutect2, pindel, varscan2
- MEFV | c.1587G>A p.Q529= | Splice Region (SNP) | VAF 227/965 reads (24%) | called by muse, mutect2, varscan2
- MEOX1 | c.129C>G p.F43L | Missense Mutation (SNP) | VAF 42/544 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.279); called by muse, mutect2
- METTL11B | c.497T>A p.V166E | Missense Mutation (SNP) | VAF 295/1287 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- METTL2B | c.409A>G p.M137V | Missense Mutation (SNP) | VAF 77/1410 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- MIA3 | c.1665G>C p.E555D | Missense Mutation (SNP) | VAF 80/572 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MIDEAS | c.2875C>T p.R959* | Nonsense Mutation (SNP) | VAF 40/1040 reads (4%) | called by muse, mutect2
- MROH5 | c.1155G>C p.Q385H | Missense Mutation (SNP) | VAF 45/419 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MROH7 | c.3330G>T p.K1110N | Missense Mutation (SNP) | VAF 74/313 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MROH9 | c.1598T>A p.V533E | Missense Mutation (SNP) | VAF 41/558 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- MTA2 | c.1730G>T p.R577M | Missense Mutation (SNP) | VAF 104/833 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- MTNR1A | c.20C>G p.A7G | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- MTR | c.1597G>T p.D533Y | Missense Mutation (SNP) | VAF 84/1033 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MUC16 | c.42047T>C p.L14016P | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC16 | c.26698A>T p.T8900S | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- MUC16 | c.24140C>A p.T8047K | Missense Mutation (SNP) | VAF 111/544 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- MUC17 | c.3596C>A p.S1199* | Nonsense Mutation (SNP) | VAF 58/675 reads (9%) | called by muse, mutect2
- MUC20 | c.1196C>A p.S399* | Nonsense Mutation (SNP) | VAF 333/1927 reads (17%) | called by muse, varscan2
- MUC3A | c.521A>T p.Y174F | Missense Mutation (SNP) | VAF 134/547 reads (24%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- MYH7B | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 174/842 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- MYH8 | c.5365C>A p.L1789M | Missense Mutation (SNP) | VAF 398/1482 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- MYO16 | c.1600T>A p.C534S | Missense Mutation (SNP) | VAF 47/420 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- MYO18A | c.2389G>C p.E797Q | Missense Mutation (SNP) | VAF 46/552 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.129); called by muse, mutect2
- MYO1E | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 106/883 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MYO7A | c.1081-1G>T p.X361_splice | Splice Site (SNP) | VAF 37/259 reads (14%) | called by muse, mutect2, varscan2
- MYOM2 | c.1115T>A p.V372D | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- MYPN | c.94A>T p.R32W | Missense Mutation (SNP) | VAF 52/640 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- MYT1 | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 17/543 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NAA40 | c.411-7C>T | Splice Region (SNP) | VAF 18/474 reads (4%) | called by muse, mutect2
- NAT16 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 20/625 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- NDUFB11 | c.342G>A p.M114I (on ENST00000377811 / NM_001135998.3; = p.M124I on NM_019056.6) | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NELL2 | c.481del p.H161Ifs*2 | Frame Shift Del (DEL) | VAF 81/349 reads (23%) | called by mutect2, pindel, varscan2
- NES | c.3134C>A p.S1045* | Nonsense Mutation (SNP) | VAF 18/193 reads (9%) | called by muse, mutect2
- NLRC3 | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 205/683 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRP13 | c.778C>A p.Q260K | Missense Mutation (SNP) | VAF 46/424 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NLRP5 | c.2199G>T p.L733F | Missense Mutation (SNP) | VAF 202/747 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NME8 | c.443G>T p.C148F | Missense Mutation (SNP) | VAF 68/756 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- NOS1 | c.3910G>T p.A1304S | Missense Mutation (SNP) | VAF 50/960 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); called by muse, mutect2
- NOS1 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 47/784 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOTO | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 95/384 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NR5A1 | c.1135C>A p.L379M | Missense Mutation (SNP) | VAF 62/818 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); called by muse, mutect2
- NRROS | c.88T>A p.S30T | Missense Mutation (SNP) | VAF 35/444 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.073); called by muse, mutect2
- OAS2 | c.704A>G p.Q235R | Missense Mutation (SNP) | VAF 117/945 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OBI1 | c.874A>T p.K292* | Nonsense Mutation (SNP) | VAF 76/296 reads (26%) | called by muse, mutect2, varscan2
- OBSCN | c.6512dup p.L2172Afs*8 | Frame Shift Ins (INS) | VAF 55/293 reads (19%) | called by mutect2, pindel, varscan2
- OGFRL1 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 57/455 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- OR10P1 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 150/524 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR11H1 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 84/442 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.363); called by mutect2, varscan2
- OR11H2 | c.518G>A p.C173Y (on ENST00000556246; = p.C184Y on NM_001197287.1) | Missense Mutation (SNP) | VAF 247/1671 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR1L3 | c.553C>A p.L185M | Missense Mutation (SNP) | VAF 20/325 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.491); called by muse, mutect2
- OR2AE1 | c.508G>T p.G170W | Missense Mutation (SNP) | VAF 109/477 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR2T2 | c.497G>T p.S166I | Missense Mutation (SNP) | VAF 177/1555 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- OR2V2 | c.156G>C p.M52I | Missense Mutation (SNP) | VAF 99/857 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4B1 | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 70/284 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4K17 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 74/346 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- OR56A3 | c.22A>T p.T8S | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- OR6Q1 | c.766T>C p.Y256H | Missense Mutation (SNP) | VAF 151/730 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- OR9A2 | c.642C>A p.Y214* | Nonsense Mutation (SNP) | VAF 32/454 reads (7%) | called by muse, mutect2
- OSBPL10 | c.1895A>G p.Y632C | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OTOP1 | c.1605G>T p.Q535H | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OVCH1 | c.3148A>T p.K1050* | Nonsense Mutation (SNP) | VAF 22/244 reads (9%) | called by muse, mutect2
- OVCH1 | c.2516G>C p.S839T | Missense Mutation (SNP) | VAF 116/499 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- PCDH18 | c.1251C>G p.I417M | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PCDH19 | c.1735C>A p.R579S | Missense Mutation (SNP) | VAF 60/484 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- PCDH7 | c.2471del p.K825Sfs*63 | Frame Shift Del (DEL) | VAF 98/441 reads (22%) | called by mutect2, pindel, varscan2
- PCDHB10 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 130/1001 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- PCDHB9 | c.1946A>T p.E649V | Missense Mutation (SNP) | VAF 108/1552 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2
- PCDHGA11 | c.785T>A p.V262E | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- PCDHGA12 | c.751G>T p.V251F | Missense Mutation (SNP) | VAF 91/723 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDHGA3 | c.1843G>T p.G615* | Nonsense Mutation (SNP) | VAF 155/775 reads (20%) | called by muse, mutect2, varscan2
- PCDHGB2 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 91/960 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCSK5 | c.1690G>C p.A564P | Missense Mutation (SNP) | VAF 32/508 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); called by muse, mutect2
- PDE10A | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 59/252 reads (23%) | called by muse, mutect2, varscan2
- PDE1A | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 26/293 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.292); called by muse, mutect2
- PDE3A | c.2926G>T p.G976C | Missense Mutation (SNP) | VAF 47/389 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDPR | c.800A>T p.Y267F | Missense Mutation (SNP) | VAF 93/1327 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); called by muse, mutect2
- PEX12 | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 129/1084 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- PGGT1B | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 89/488 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PGP | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 77/717 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHRF1 | c.2547G>T p.R849S (on ENST00000264555 / NM_001286581.2; = p.R848S on NM_020901.4) | Missense Mutation (SNP) | VAF 100/385 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIBF1 | c.1028G>C p.R343T | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PKDCC | c.1246A>G p.T416A | Missense Mutation (SNP) | VAF 57/594 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- PKHD1L1 | c.7118T>A p.L2373H | Missense Mutation (SNP) | VAF 152/688 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- PLCB4 | c.2746C>A p.Q916K | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PLD5 | c.1239dup p.K414* (on ENST00000442594; = p.K352* on NM_001195811.1 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 24/208 reads (12%) | called by pindel, varscan2
- PLEKHA6 | c.755C>A p.P252H | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLIN4 | c.2990C>T p.A997V (on ENST00000301286; = p.A1012V on NM_001367868.2) | Missense Mutation (SNP) | VAF 73/737 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PLXNA4 | c.4892C>T p.P1631L | Missense Mutation (SNP) | VAF 72/718 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- PMP2 | c.23C>A p.T8N | Missense Mutation (SNP) | VAF 131/634 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- POLR3H | c.584T>A p.L195Q | Missense Mutation (SNP) | VAF 46/364 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POPDC2 | c.991C>G p.P331A | Missense Mutation (SNP) | VAF 90/855 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- POTEH | c.1066A>T p.S356C | Missense Mutation (SNP) | VAF 100/1939 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- POTEJ | c.1865G>T p.R622I | Missense Mutation (SNP) | VAF 169/1639 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- PPFIA3 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- PPM1G | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 183/753 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PPP1R12C | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 15/242 reads (6%) | called by muse, mutect2
- PRAMEF17 | c.367T>G p.S123A | Missense Mutation (SNP) | VAF 92/878 reads (10%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- PRDM13 | c.979G>T p.G327C | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- PREX2 | c.539del p.L180* | Frame Shift Del (DEL) | VAF 51/454 reads (11%) | called by mutect2, pindel, varscan2
- PRIMA1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 102/363 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- PRRC2C | c.3103G>T p.E1035* (on ENST00000367742; = p.E1033* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 68/620 reads (11%) | called by muse, mutect2, varscan2
- PRRC2C | c.7082C>T p.S2361L (on ENST00000367742; = p.S2359L on NM_015172.4) | Missense Mutation (SNP) | VAF 40/1432 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- PRTG | c.1256C>A p.P419H | Missense Mutation (SNP) | VAF 91/799 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSG9 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2
- PSME2 | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.151); called by muse, mutect2
- PSME4 | c.2497G>T p.G833* | Nonsense Mutation (SNP) | VAF 42/619 reads (7%) | called by muse, mutect2
- PTCRA | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 76/349 reads (22%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PTGER3 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTGIS | c.588C>A p.D196E | Missense Mutation (SNP) | VAF 180/1073 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- PTPN14 | c.1430A>T p.Y477F | Missense Mutation (SNP) | VAF 69/950 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2
- PTPRT | c.3543C>A p.T1181= | Splice Region (SNP) | VAF 51/320 reads (16%) | called by muse, mutect2, varscan2
- PTPRT | c.1220G>T p.W407L | Missense Mutation (SNP) | VAF 95/801 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PTPRZ1 | c.125-2A>T p.X42_splice | Splice Site (SNP) | VAF 100/355 reads (28%) | called by muse, mutect2, varscan2
- RAD51AP2 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 153/550 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- RADIL | c.2089C>G p.L697V | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RADIL | c.1885C>A p.H629N | Missense Mutation (SNP) | VAF 124/513 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAET1L | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 231/1043 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAPGEF1 | c.1886G>C p.R629T | Missense Mutation (SNP) | VAF 39/504 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.029); called by muse, mutect2
- RAPGEF3 | c.2727C>A p.D909E (on ENST00000389212; = p.D867E on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/942 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- RBL2 | c.2009A>G p.Y670C | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RBM6 | c.1342G>T p.G448C | Missense Mutation (SNP) | VAF 68/591 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- RBP3 | c.3278C>A p.P1093H | Missense Mutation (SNP) | VAF 132/1095 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- RBPMS2 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 42/305 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- RCOR1 | c.1138C>G p.Q380E | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RFX1 | c.1454G>T p.R485L | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGS20 | c.559G>A p.A187T (on ENST00000297313 / NM_170587.4; = p.A40T on NM_003702.4) | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RGSL1 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RNF150 | c.232G>T p.G78* | Nonsense Mutation (SNP) | VAF 45/317 reads (14%) | called by muse, mutect2, varscan2
- RNF182 | c.484A>T p.T162S | Missense Mutation (SNP) | VAF 71/351 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF182 | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 69/348 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF5 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 22/492 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2
- ROR2 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 108/1517 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.122); called by muse, mutect2
- RP1 | c.2435dup p.M813Nfs*7 | Frame Shift Ins (INS) | VAF 52/496 reads (10%) | called by mutect2, pindel, varscan2
- RP1 | c.3241G>A p.V1081M | Missense Mutation (SNP) | VAF 33/402 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); called by muse, mutect2
- RP2 | c.445C>A p.Q149K | Missense Mutation (SNP) | VAF 100/605 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- RPUSD2 | c.1296G>C p.E432D | Missense Mutation (SNP) | VAF 62/578 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.042); called by muse, varscan2
- RPUSD2 | c.1389G>T p.K463N | Missense Mutation (SNP) | VAF 68/486 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, varscan2
- RTEL1 | c.3095G>T p.R1032M | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.117); called by muse, mutect2
- RTL5 | c.450del p.P151Lfs*3 | Frame Shift Del (DEL) | VAF 115/435 reads (26%) | called by mutect2, pindel, varscan2
- RUBCN | c.2646+3G>A | Splice Region (SNP) | VAF 179/1309 reads (14%) | called by muse, mutect2, varscan2
- RUSC1 | c.487T>G p.S163A | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- RYR3 | c.5970T>A p.Y1990* | Nonsense Mutation (SNP) | VAF 123/958 reads (13%) | called by muse, mutect2, varscan2
- RYR3 | c.8767A>T p.T2923S (on ENST00000389232; = p.T2924S on NM_001036.6) | Missense Mutation (SNP) | VAF 56/372 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SARDH | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 81/668 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SBSN | c.1507G>T p.D503Y (on ENST00000452271 / NM_001166034.2; = p.D160Y on NM_198538.4) | Missense Mutation (SNP) | VAF 83/741 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SCYL2 | c.2418G>A p.M806I | Missense Mutation (SNP) | VAF 76/827 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2
- SEC16B | c.1000del p.E334Kfs*9 | Frame Shift Del (DEL) | VAF 158/1152 reads (14%) | called by mutect2, pindel, varscan2
- SELENOP | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.423); called by muse, varscan2
- SERPINA5 | c.43C>A p.Q15K | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SETD1A | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 186/993 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SFXN3 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 155/502 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SGK3 | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 106/458 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- SGO2 | c.3364G>C p.E1122Q | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SHANK1 | c.3349G>A p.E1117K | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, varscan2
- SHOX | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 144/876 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- SHOX2 | c.523C>T p.Q175* (on ENST00000441443 / NM_006884.3; = p.Q199* on NM_003030.4) | Nonsense Mutation (SNP) | VAF 117/947 reads (12%) | called by muse, mutect2, varscan2
- SI | c.5108+1G>A p.X1703_splice | Splice Site (SNP) | VAF 56/764 reads (7%) | called by muse, mutect2
- SIDT1 | c.2389C>T p.L797F | Missense Mutation (SNP) | VAF 74/638 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIGLEC1 | c.2737G>T p.V913F | Missense Mutation (SNP) | VAF 86/447 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SIRPA | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 229/1711 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIX5 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 28/274 reads (10%) | called by muse, mutect2
- SLAMF8 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 171/768 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- SLC22A24 | c.944T>G p.L315R | Missense Mutation (SNP) | VAF 63/346 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC24A2 | c.971C>A p.A324D | Missense Mutation (SNP) | VAF 130/1140 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC2A5 | c.925G>T p.V309L | Missense Mutation (SNP) | VAF 106/468 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- SLC35F3 | c.1149C>G p.I383M (on ENST00000366617 / NM_001300845.1; = p.I452M on NM_173508.4) | Missense Mutation (SNP) | VAF 316/1802 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC38A4 | c.1249C>A p.L417M | Missense Mutation (SNP) | VAF 35/584 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.384); called by muse, mutect2
- SLC44A3 | c.263A>T p.D88V (on ENST00000271227 / NM_001114106.3; = p.D40V on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SLC7A5 | c.586G>T p.V196F | Missense Mutation (SNP) | VAF 129/500 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC8A1 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- SLURP1 | c.308T>A p.L103H | Missense Mutation (SNP) | VAF 160/758 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- SMO | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.38); called by muse, mutect2
- SNRPE | c.279G>C p.*93Yext*2 | Nonstop Mutation (SNP) | VAF 32/344 reads (9%) | called by muse, mutect2
- SPAG17 | c.5671A>T p.K1891* | Nonsense Mutation (SNP) | VAF 111/523 reads (21%) | called by muse, mutect2, varscan2
- SPAG17 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 73/854 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2
- SPATA18 | c.204T>G p.N68K | Missense Mutation (SNP) | VAF 40/373 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- SPEG | c.3044G>T p.C1015F | Missense Mutation (SNP) | VAF 155/651 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPIN4 | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 79/247 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SPINK5 | c.2879C>A p.A960D | Missense Mutation (SNP) | VAF 101/887 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SPOCD1 | c.3242G>A p.R1081K | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SPRED3 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 42/366 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- SPTBN4 | c.3916G>C p.E1306Q | Missense Mutation (SNP) | VAF 88/911 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.223); called by muse, mutect2
- SRCAP | c.991C>A p.P331T | Missense Mutation (SNP) | VAF 30/1096 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- SRRM2 | c.6538A>T p.R2180W | Missense Mutation (SNP) | VAF 156/878 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SRSF1 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 123/776 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- STAB1 | c.2474C>A p.T825K | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- STAB2 | c.418-1G>T p.X140_splice | Splice Site (SNP) | VAF 102/892 reads (11%) | called by muse, mutect2, varscan2
- STAT1 | c.1789G>A p.G597R | Missense Mutation (SNP) | VAF 400/1798 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STIM2 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 69/453 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- STRA8 | c.922G>A p.A308T (on ENST00000275764; = p.A286T on NM_182489.2) | Missense Mutation (SNP) | VAF 42/441 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STXBP3 | c.871A>G p.R291G | Missense Mutation (SNP) | VAF 64/453 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- SUPT6H | c.4085del p.K1362Rfs*6 | Frame Shift Del (DEL) | VAF 277/1796 reads (15%) | called by mutect2, pindel, varscan2
- SYCP3 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 37/558 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); called by muse, mutect2
- SYTL3 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 56/651 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); called by muse, mutect2
- TBC1D3B | c.29G>A p.W10* | Nonsense Mutation (SNP) | VAF 165/4552 reads (4%) | called by muse, mutect2
- TBXA2R | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 107/559 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEC | c.754A>T p.M252L | Missense Mutation (SNP) | VAF 78/332 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM2 | c.8167C>A p.R2723S (on ENST00000518659 / NM_001122679.2; = p.R2484S on NM_001080428.3) | Missense Mutation (SNP) | VAF 135/507 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TERF1 | c.659A>T p.Q220L | Missense Mutation (SNP) | VAF 95/464 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- TEX14 | c.4492T>G p.*1498Gext*47 (on ENST00000240361 / NM_001201457.2; = p.*1452Gext*47 on NM_031272.5) | Nonstop Mutation (SNP) | VAF 128/682 reads (19%) | called by muse, mutect2, varscan2
- TEX44 | c.760C>G p.L254V | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- TFAP2D | c.1187G>A p.S396N | Missense Mutation (SNP) | VAF 97/689 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TGFBR3 | c.1906A>T p.I636F | Missense Mutation (SNP) | VAF 56/563 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TGM6 | c.81C>A p.C27* | Nonsense Mutation (SNP) | VAF 352/1102 reads (32%) | called by muse, mutect2, varscan2
- THSD7A | c.4163G>C p.C1388S | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.18); called by muse, mutect2
- TIAM1 | c.647C>A p.T216K | Missense Mutation (SNP) | VAF 92/952 reads (10%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.007); called by muse, mutect2
- TIAM1 | c.177C>A p.S59R | Missense Mutation (SNP) | VAF 62/670 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TIE1 | c.3311C>A p.A1104E | Missense Mutation (SNP) | VAF 107/506 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- TIMP3 | c.56G>T p.W19L | Missense Mutation (SNP) | VAF 70/641 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLL1 | c.2219G>T p.G740V | Missense Mutation (SNP) | VAF 222/968 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLN1 | c.3986del p.P1329Lfs*14 | Frame Shift Del (DEL) | VAF 71/515 reads (14%) | called by mutect2, pindel, varscan2
- TMEM201 | c.385_392del p.T129Dfs*16 | Frame Shift Del (DEL) | VAF 36/336 reads (11%) | called by mutect2, pindel
- TMEM61 | c.523C>A p.P175T | Missense Mutation (SNP) | VAF 146/1649 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNFRSF10B | c.635C>G p.S212* | Nonsense Mutation (SNP) | VAF 36/1074 reads (3%) | called by muse, mutect2
- TNFRSF9 | c.499C>G p.P167A | Missense Mutation (SNP) | VAF 74/671 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- TNK2 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 45/526 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- TNKS1BP1 | c.4837C>G p.P1613A | Missense Mutation (SNP) | VAF 78/421 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNR | c.3866A>T p.N1289I | Missense Mutation (SNP) | VAF 125/956 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TRAF5 | c.341C>G p.P114R | Missense Mutation (SNP) | VAF 45/652 reads (7%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRAV12-2 | c.238G>T p.G80* | Nonsense Mutation (SNP) | VAF 66/746 reads (9%) | called by muse, mutect2
- TRGC1 | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- TRIM13 | c.478C>A p.R160S | Missense Mutation (SNP) | VAF 57/229 reads (25%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
417 further variants in this file (60 protein-altering or splice-affecting, 225 silent, 132 other) are not listed here.
